Somatic mutation profile of tumor specimen TCGA-CG-4442-01A (aliquot TCGA-CG-4442-01A-01D-1158-08) from TCGA case TCGA-CG-4442, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 85.8 years (31,350 days).
Specimen TCGA-CG-4442-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0e1ba61-0c33-4f98-85bb-5d4d856752a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4442-10A (Blood Derived Normal), aliquot TCGA-CG-4442-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2bc5106-3734-448e-a6a4-bd8ba98e1858

The open-access MAF lists 1,715 somatic variants for this specimen: 1,315 protein-altering or splice-affecting, 358 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 830, Silent 358, Frame Shift Del 329, Frame Shift Ins 70, Nonsense Mutation 39, Intron 27, Splice Site 21, Splice Region 14, In Frame Del 8, RNA 7, 3'Flank 3, 3'UTR 2.

Variants (750 of 1,715; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.910del p.T304Qfs*23 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 87/283 reads (31%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL5A1 | c.2988dup p.G997Rfs*17 | Frame Shift Ins (INS) | VAF 50/182 reads (27%) | catalogued as rs764693725; ClinVar: pathogenic; called by mutect2, varscan2
- CTNS | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs113994208, CM980456, COSV50443347; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.9767dup p.S3257Qfs*2 | Frame Shift Ins (INS) | VAF 53/98 reads (54%) | catalogued as rs398124103; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DOK7 | c.1263del p.S422Hfs*34 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs606231129; ClinVar: pathogenic; called by pindel, varscan2
- GCDH | c.1173del p.N392Mfs*9 | Frame Shift Del (DEL) | VAF 49/160 reads (31%) | catalogued as rs754002357; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 65/242 reads (27%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 50/158 reads (32%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.303del p.S102Afs*28 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs797045661, CD160605; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MKRN3 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1264639964, CM1512773, COSV100091280, COSV58811855; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 60/94 reads (64%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 50/130 reads (38%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PANK2 | c.1257del p.F419Lfs*31 (on ENST00000316562 / NM_153638.3; = p.F128Lfs*31 on NM_024960.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 170/468 reads (36%) | catalogued as rs1568574931; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 36/70 reads (51%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 61/149 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PLEC | c.5086C>T p.R1696* (on ENST00000322810 / NM_201380.4; = p.R1586* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs782185897, COSV59686763; ClinVar: pathogenic; called by muse, mutect2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 62/183 reads (34%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TREX1 | c.144dup p.T49Hfs*53 (on ENST00000625293 / NM_033629.6; = p.T39Hfs*53 on NM_007248.5) | Frame Shift Ins (INS) | VAF 62/194 reads (32%) | catalogued as rs748914604; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AAK1 | c.1574A>C p.Q525P | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.888); catalogued as COSV68646325; called by muse, mutect2
- ABCA5 | c.128dup p.L43Ffs*8 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs751512043; called by mutect2, varscan2
- ABCD2 | c.46A>G p.R16G | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV58054533; called by muse, mutect2, varscan2
- ABCG2 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV52948771; called by muse, mutect2, varscan2
- ABCG4 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV56645449; called by muse, mutect2, varscan2
- ABT1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.91); catalogued as rs782010945, COSV51292132; called by muse, mutect2, varscan2
- AC092143.1 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59247998; called by muse, mutect2, varscan2
- ACACA | c.5248C>T p.R1750C | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1255086287; called by muse, mutect2, varscan2
- ACP3 | c.968+1G>A p.X323_splice | Splice Site (SNP) | VAF 25/86 reads (29%) | catalogued as COSV60488289; called by muse, mutect2, varscan2
- ACRBP | c.779C>A p.S260Y | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV57524201; called by muse, mutect2, varscan2
- ACSM2A | c.1291G>A p.D431N (on ENST00000219054; = p.D352N on NM_001308169.2) | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs749299994, COSV54583784; called by muse, mutect2, varscan2
- ACTR10 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54299775; called by muse, mutect2, varscan2
- ACVR1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs764097240, COSV55122237; called by muse, mutect2, varscan2
- ADAM7 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); catalogued as rs376045894; called by muse, mutect2, varscan2
- ADAMTS16 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 100/316 reads (32%) | catalogued as COSV57004770; called by muse, mutect2, varscan2
- ADAMTS18 | c.2069A>G p.N690S | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1261874269, COSV51422018; called by muse, mutect2, varscan2
- ADAMTSL3 | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54465804; called by muse, mutect2, varscan2
- ADCY6 | c.2443T>C p.Y815H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV57170093; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 58/184 reads (32%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRE3 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53734204; called by muse, mutect2
- ADGRF4 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV51956752; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 94/240 reads (39%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV62426641; called by muse, varscan2
- ADNP | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 138/512 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62426645; called by muse, varscan2
- ADSS1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290246650, COSV58274020; called by muse, mutect2, varscan2
- AFAP1L1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs570213105, COSV57044628; called by muse, mutect2, varscan2
- AFF4 | c.3404T>G p.I1135S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV54798722; called by muse, mutect2, varscan2
- AGO1 | c.491T>C p.M164T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64596347; called by muse, mutect2, varscan2
- AGPAT3 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52373601; called by muse, mutect2
- AHNAK | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57227303; called by muse, mutect2, varscan2
- AIPL1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs200899521, CD076724, CM078178, COSV51508582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.3643A>G p.T1215A | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV62356170; called by muse, mutect2, varscan2
- AL121899.2 | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67352163; called by muse, mutect2, varscan2
- AL645922.1 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs767253167, COSV54962295; called by muse, mutect2, varscan2
- ALCAM | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60253786; called by muse, mutect2, varscan2
- ALG1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs771007321, COSV52159114; called by muse, mutect2, varscan2
- ALOX5 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 119/400 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1228958487, COSV65554088; called by muse, mutect2, varscan2
- AMD1 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV64388040; called by muse, mutect2, varscan2
- AMH | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV55556612; called by muse, mutect2, varscan2
- AMT | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs150649086; called by muse, mutect2, varscan2
- AMY2B | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.237); catalogued as rs550567671, COSV100796408; called by muse, mutect2
- ANAPC1 | c.2000T>C p.M667T | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV61978968; called by muse, mutect2, varscan2
- ANK3 | c.12245-2A>G p.X4082_splice (on ENST00000280772 / NM_001320874.2; = p.X603_splice on NM_001149.3) | Splice Site (SNP) | VAF 53/182 reads (29%) | catalogued as COSV55077969; called by muse, mutect2, varscan2
- ANKRD11 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56369901; called by muse, mutect2, varscan2
- ANKRD52 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1287477445, COSV57282224; called by muse, mutect2
- ANO1 | c.2449T>C p.Y817H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62449220; called by muse, mutect2, varscan2
- AOC1 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV62870543; called by muse, mutect2, varscan2
- AP2A2 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59963660; called by muse, varscan2
- AP5B1 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as COSV100376160; called by muse, mutect2, varscan2
- APBA1 | c.2182-1G>T p.X728_splice | Splice Site (SNP) | VAF 48/123 reads (39%) | catalogued as COSV55235655, COSV99597272; called by muse, mutect2, varscan2
- APBB1 | c.498T>A p.D166E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54980003; called by muse, mutect2, varscan2
- APBB1IP | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV63304137; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 37/108 reads (34%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAF | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51691648, COSV51694952; called by muse, mutect2, varscan2
- ARAP1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.167); catalogued as rs1290998332, COSV61991579; called by muse, mutect2
- ARCN1 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 197/554 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV50615490; called by muse, mutect2, varscan2
- ARHGAP35 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs759238695, COSV68331722; called by muse, mutect2, varscan2
- ARHGAP5 | c.2676del p.F892Lfs*9 | Frame Shift Del (DEL) | VAF 40/133 reads (30%) | catalogued as rs781483073; called by mutect2, pindel, varscan2
- ARHGAP9 | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as COSV62724329; called by muse, mutect2, varscan2
- ARHGEF18 | c.1291C>T p.L431F (on ENST00000359920 / NM_001130955.2; = p.L327F on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.257); catalogued as COSV60473350; called by muse, mutect2, varscan2
- ARNT | c.1783del p.R595Gfs*11 | Frame Shift Del (DEL) | VAF 54/200 reads (27%) | catalogued as COSV62230627; called by mutect2, pindel, varscan2
- ART1 | c.735del p.F246Lfs*6 | Frame Shift Del (DEL) | VAF 44/158 reads (28%) | catalogued as rs762428866, COSV99167258; called by mutect2, pindel, varscan2
- ASAP1 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs774096816, COSV63053663, COSV63053752; called by muse, mutect2, varscan2
- ASAP1 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 131/527 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV63053670; called by muse, mutect2, varscan2
- ASAP1 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as rs761895160, COSV63053676; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | catalogued as rs747570359; called by mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 106/298 reads (36%) | catalogued as rs761154268; called by mutect2, varscan2
- ASIC3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs746657424, COSV52525344; called by muse, mutect2, varscan2
- ASNS | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs1383821157, COSV51555415; called by muse, mutect2, varscan2
- ATAD2 | c.3578C>T p.A1193V | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs756836955, COSV54885687; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 44/125 reads (35%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP13A3 | c.1027G>T p.G343* | Nonsense Mutation (SNP) | VAF 45/143 reads (31%) | catalogued as COSV55468905; called by muse, mutect2, varscan2
- ATP2B2 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 251/749 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59506099; called by muse, mutect2, varscan2
- ATP6V0D1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1390138049, COSV52099622; called by muse, mutect2, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs1268253442; called by mutect2, pindel, varscan2
- AWAT2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV52144413; called by muse, mutect2, varscan2
- B4GALT2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753886330, COSV52543251; called by muse, mutect2, varscan2
- B4GALT6 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778061781, COSV52704920; called by muse, mutect2, varscan2
- BACH2 | c.1826G>T p.R609M | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57605092; called by muse, mutect2, varscan2
- BACH2 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs576225753, COSV57590828; called by muse, mutect2, varscan2
- BANK1 | c.1703A>G p.E568G | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59848773; called by muse, mutect2, varscan2
- BARHL1 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778876265, COSV55036805; called by muse, varscan2
- BATF | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54376709; called by muse, mutect2, varscan2
- BAZ1B | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 125/470 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59993981; called by muse, mutect2, varscan2
- BBS10 | c.805del p.S269Pfs*9 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as COSV99675211; called by mutect2, pindel, varscan2
- BCAM | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV54304525; called by muse, mutect2, varscan2
- BCAS1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs757394101, COSV65086533, COSV65089297; called by muse, mutect2, varscan2
- BCL2L14 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV53793028; called by muse, mutect2, varscan2
- BCL6 | c.1418dup p.K474Efs*26 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs770320988; called by pindel, varscan2
- BCL7C | c.617dup p.L207Tfs*10 | Frame Shift Ins (INS) | VAF 102/279 reads (37%) | catalogued as rs754078059; called by mutect2, varscan2
- BCL9L | c.3273G>A p.M1091I | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52688571; called by muse, varscan2
- BCOR | c.2749A>G p.T917A | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV60716409; called by muse, mutect2, varscan2
- BEGAIN | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs920378283, COSV62069990; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 99/250 reads (40%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BICD2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV63550648; called by muse, mutect2, varscan2
- BLZF1 | c.962del p.K321Rfs*21 | Frame Shift Del (DEL) | VAF 49/174 reads (28%) | catalogued as rs1557849884; called by mutect2, pindel, varscan2
- BMP5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752442881, COSV63702034; called by muse, mutect2, varscan2
- BNIP3 | c.646A>G p.M216V | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV64044302; called by muse, mutect2, varscan2
- BOD1L1 | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 104/315 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV50050197; called by muse, mutect2, varscan2
- BRCA1 | c.4190G>T p.R1397M | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV58797796; called by muse, mutect2, varscan2
- BRCA1 | c.2971A>C p.K991Q | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58797814; called by muse, mutect2, varscan2
- BSN | c.11128C>A p.R3710S | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV56526047; called by muse, mutect2, varscan2
- BTNL8 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51461219; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 65/203 reads (32%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C10orf120 | c.704dup p.N235Kfs*28 | Frame Shift Ins (INS) | VAF 28/111 reads (25%) | catalogued as rs775451807; called by mutect2, pindel, varscan2
- C11orf52 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs201067931, COSV53715121; called by muse, mutect2, varscan2
- C11orf80 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60930964; called by muse, mutect2, varscan2
- C2CD3 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as rs750328756, COSV58097023; called by muse, varscan2
- C2orf16 | c.1748C>T p.T583I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV62677900; called by muse, mutect2, varscan2
- C3orf22 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as rs373190783; called by muse, mutect2, varscan2
- C5 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1350185556, COSV56331557; called by muse, mutect2, varscan2
- C7orf26 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as rs760621694, COSV60420252; called by muse, mutect2, varscan2
- CA7 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV58156239; called by muse, mutect2, varscan2
- CABP5 | c.433del p.R145Gfs*24 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | catalogued as rs769959570, COSV99506527; called by mutect2, pindel, varscan2
- CACNA1A | c.5044A>G p.T1682A | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64210400; called by muse, mutect2, varscan2
- CACNA1C | c.4184G>A p.R1395Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs759855917, COSV59712736; called by muse, mutect2, varscan2
- CACNA1E | c.1475G>A p.C492Y | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62414760; called by muse, mutect2, varscan2
- CACNG5 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV50059097; called by muse, mutect2, varscan2
- CAMSAP3 | c.931T>C p.F311L | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as COSV50353639; called by muse, mutect2
- CAPN1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1423509575, COSV54199878; called by muse, mutect2, varscan2
- CAPN12 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs373985954; called by muse, mutect2, varscan2
- CARD10 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52659569; called by muse, mutect2, varscan2
- CAT | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53811533, COSV53812949; called by muse, mutect2, varscan2
- CAVIN1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.094); catalogued as rs1008285930, COSV63812638; called by muse, mutect2, varscan2
- CBARP | c.1108del p.D370Mfs*37 (on ENST00000382477; = p.D350Mfs*40 on NM_152769.3) | Frame Shift Del (DEL) | VAF 35/122 reads (29%) | catalogued as COSV99289301; called by mutect2, pindel, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CBX6 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1412443506, COSV53321862; called by muse, mutect2, varscan2
- CBY2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs761413589, COSV60117619; called by muse, varscan2
- CBY2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs149478922; called by muse, varscan2
- CCAR1 | c.1117T>C p.C373R | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.162); catalogued as COSV56273605; called by muse, mutect2, varscan2
- CCDC107 | c.852A>G p.*284Wext*21 | Nonstop Mutation (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100526359; called by muse, mutect2
- CCDC136 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs751743986, COSV52802160; called by muse, mutect2, varscan2
- CCDC142 | c.1717G>A p.A573T (on ENST00000393965 / NM_001365575.2; = p.A566T on NM_032779.4) | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV50688948; called by muse, varscan2
- CCDC151 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV62699039; called by muse, mutect2, varscan2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 56/188 reads (30%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC180 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs545586330, COSV63833442; called by muse, mutect2, varscan2
- CCDC33 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771474460, COSV58356984; called by muse, mutect2, varscan2
- CCDC74B | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763710118, COSV60100631; called by muse, mutect2, varscan2
- CCDC88A | c.2032dup p.T678Nfs*4 | Frame Shift Ins (INS) | VAF 26/73 reads (36%) | catalogued as rs750732366; called by mutect2, varscan2
- CD1A | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs200592984, COSV56862534; called by muse, mutect2, varscan2
- CD1B | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63805065; called by muse, mutect2, varscan2
- CD1E | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV63772622; called by muse, mutect2
- CD248 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs1361343966, COSV100256748; called by muse, mutect2, varscan2
- CD300LD | c.474-1G>T p.X158_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100943996; called by muse, mutect2
- CD40 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs770177808, COSV64848220; called by muse, mutect2, varscan2
- CD6 | c.839T>A p.V280E | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57841880; called by muse, mutect2, varscan2
- CDCA2 | c.2722A>G p.I908V | Missense Mutation (SNP) | VAF 108/571 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV57948212; called by muse, mutect2, varscan2
- CDH17 | c.2334C>A p.H778Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV50338627; called by muse, mutect2, varscan2
- CDH22 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV64836451, COSV64837465; called by muse, mutect2, varscan2
- CDH23 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as rs370549448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH24 | c.1887G>T p.E629D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.351); catalogued as COSV99944264; called by muse, mutect2, varscan2
- CDH4 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs1309693430, COSV64671463; called by muse, mutect2, varscan2
- CDH4 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759379228, COSV64645806; called by muse, mutect2, varscan2
- CDH7 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs533419487, COSV59888578; called by muse, mutect2, varscan2
- CDK12 | c.2768G>T p.G923V | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71002626; called by muse, mutect2, varscan2
- CDK14 | c.1307T>G p.F436C (on ENST00000380050 / NM_001287135.2; = p.F418C on NM_012395.3) | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56049414; called by muse, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 58/212 reads (27%) | catalogued as rs759091263; called by mutect2, varscan2
- CEACAM20 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV57603071; called by muse, mutect2, varscan2
- CECR2 | c.2377G>A p.V793I (on ENST00000342247 / NM_001290047.2; = p.V610I on NM_001290046.1) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as rs893590232, COSV52847071; called by muse, mutect2, varscan2
- CEL | c.1702del p.D568Tfs*139 (on ENST00000673714; = p.D565Tfs*139 on NM_001807.6) | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV60828783; called by pindel, varscan2
- CELF4 | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.16); catalogued as COSV58464106; called by muse, mutect2, varscan2
- CELF6 | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54718375; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | catalogued as rs1325731082; called by mutect2, varscan2
- CENPH | c.299dup p.L101Afs*13 | Frame Shift Ins (INS) | VAF 12/53 reads (23%) | catalogued as rs767679889; called by mutect2, pindel, varscan2
- CEP170B | c.2459G>T p.G820V (on ENST00000453495; = p.G749V on NM_015005.3) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs930438384, COSV69025474; called by muse, mutect2, varscan2
- CEP83 | c.556A>G p.R186G | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60410752; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 20/72 reads (28%) | catalogued as rs768479535; called by mutect2, pindel
- CES4A | c.1510C>T p.R504C (on ENST00000648724 / NM_001364782.1; = p.R406C on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs374934167; called by muse, mutect2, varscan2
- CFAP100 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV61504323; called by muse, mutect2, varscan2
- CFAP251 | c.1698C>G p.D566E | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV56614984; called by muse, mutect2, varscan2
- CFAP52 | c.981A>G p.I327M | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as COSV55348602; called by muse, mutect2, varscan2
- CHD4 | c.3966A>C p.K1322N (on ENST00000357008 / NM_001363606.2; = p.K1335N on NM_001273.5) | Missense Mutation (SNP) | VAF 181/474 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58909197; called by muse, mutect2, varscan2
- CHD4 | c.1520C>A p.P507H (on ENST00000357008 / NM_001363606.2; = p.P520H on NM_001273.5) | Missense Mutation (SNP) | VAF 146/429 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58909215; called by muse, mutect2, varscan2
- CHI3L1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs745563186, COSV55139907, COSV99704189; called by muse, mutect2, varscan2
- CHRM2 | c.493A>T p.I165F | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.123); catalogued as COSV57782550; called by muse, varscan2
- CHRND | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 51/143 reads (36%) | catalogued as CM012084, COSV51324139; called by muse, mutect2, varscan2
- CHRNE | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201841042, COSV53419733; called by muse, mutect2, varscan2
- CISD1 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.827); catalogued as COSV61704107; called by muse, mutect2, varscan2
- CITED2 | c.251del p.P84Rfs*63 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs748689446; called by mutect2, pindel, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/248 reads (40%) | catalogued as rs761731080; called by mutect2, varscan2
- CLCN2 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs201130753; called by muse, mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs1217596296; called by mutect2, varscan2
- CLCN6 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56742691; called by muse, mutect2, varscan2
- CLEC4A | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs375140919; called by muse, mutect2, varscan2
- CLTA | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as rs138031703; called by muse, mutect2, varscan2
- CLTCL1 | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782309571, COSV54237924; called by muse, mutect2, varscan2
- CNGB3 | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 143/526 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV60693892; called by muse, mutect2, varscan2
- CNOT1 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57778896; called by muse, mutect2
- CNOT6 | c.750del p.L251Wfs*2 | Frame Shift Del (DEL) | VAF 82/262 reads (31%) | catalogued as COSV56160927; called by mutect2, pindel, varscan2
- CNTF | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs950201643, COSV60161460; called by muse, mutect2, varscan2
- CNTNAP5 | c.639A>T p.Q213H | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV70508251; called by muse, mutect2, varscan2
- COG1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs552223280, COSV55430557; called by muse, mutect2, varscan2
- COG4 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs746367043, COSV55374649; called by muse, mutect2, varscan2
- COL20A1 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58922818, COSV58925999; called by muse, varscan2
- COL5A1 | c.5038T>A p.C1680S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65673759; called by muse, mutect2, varscan2
- COL7A1 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs751029855, COSV60402011; called by muse, mutect2, varscan2
- COLEC11 | c.276T>C p.G92= | Splice Region (SNP) | VAF 11/39 reads (28%) | catalogued as COSV52596974; called by muse, mutect2, varscan2
- COMMD5 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs759200985, COSV57384134; called by muse, mutect2, varscan2
- COP1 | c.1670A>G p.N557S | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58174492; called by muse, mutect2
- COP1 | c.1471T>C p.Y491H | Missense Mutation (SNP) | VAF 184/440 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58174502; called by muse, mutect2, varscan2
- CORO2B | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750820786, COSV55956672; called by muse, mutect2, varscan2
- CORO7 | c.2203C>A p.L735M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as COSV52033440; called by muse, mutect2, varscan2
- CPA3 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192487183, COSV56045218; called by muse, mutect2, varscan2
- CPEB2 | c.2423A>G p.Y808C | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52594984; called by muse, mutect2, varscan2
- CPN1 | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV64942730; called by muse, mutect2, varscan2
- CPN2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV60469805, COSV60471302; called by muse, mutect2, varscan2
- CPNE5 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs746485663, COSV55199120; called by muse, mutect2, varscan2
- CPSF2 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1179288271, COSV54100410; called by muse, varscan2
- CPT1A | c.1405C>A p.L469I | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV55760158; called by muse, mutect2, varscan2
- CPT1C | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs1026684162, COSV54918564, COSV54920916; called by muse, mutect2, varscan2
- CPVL | c.794del p.K265Sfs*11 | Frame Shift Del (DEL) | VAF 65/217 reads (30%) | catalogued as rs1562753933; called by mutect2, pindel, varscan2
- CR1 | c.2546A>G p.Y849C | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); catalogued as COSV65462356; called by muse, mutect2
- CREB3L1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 77/188 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV55832939; called by muse, mutect2, varscan2
- CSF3R | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs150616658, COSV58963124; called by muse, mutect2, varscan2
- CTBP2 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58337472; called by muse, mutect2, varscan2
- CTDP1 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 120/344 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1287682474, COSV50008392; called by muse, mutect2, varscan2
- CTIF | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs369410150; called by muse, mutect2, varscan2
- CTLA4 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs1357774202, COSV55593051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSK | c.158del p.N53Tfs*2 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs764168526; called by mutect2, pindel, varscan2
- CUL1 | c.1018T>G p.L340V | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV57391860; called by mutect2, varscan2
- CUL3 | c.1756A>G p.N586D | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV52369339; called by muse, mutect2
- CUX2 | c.4286dup p.A1430Cfs*11 | Frame Shift Ins (INS) | VAF 40/130 reads (31%) | catalogued as rs750550645; called by mutect2, varscan2
- CX3CL1 | c.359del p.G120Efs*42 | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | catalogued as rs1567554546, COSV104374993; called by mutect2, pindel, varscan2
- CYB5R2 | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55087190; called by muse, mutect2, varscan2
- CYP27C1 | c.650G>T p.R217M | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV58868051, COSV99080411; called by muse, mutect2, varscan2
- CYP4F22 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54111266; called by muse, mutect2, varscan2
- CYP4Z1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373398954; called by muse, varscan2
- CYRIB | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67832638; called by muse, varscan2
- CYTL1 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); catalogued as COSV57037757; called by muse, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs751187768; called by mutect2, varscan2
- DAGLA | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV57199139; called by muse, mutect2, varscan2
- DAO | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs551786568, COSV57321923; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCLK1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs760301962, COSV55184477; called by muse, mutect2, varscan2
- DCLRE1C | c.2053del p.R685Efs*6 (on ENST00000378278 / NM_001350965.2; = p.R570Efs*6 on NM_022487.4) | Frame Shift Del (DEL) | VAF 45/160 reads (28%) | catalogued as rs915913541; called by mutect2, pindel, varscan2
- DCTN2 | c.1123C>T p.Q375* (on ENST00000548249 / NM_001261413.2; = p.Q380* on NM_006400.4) | Nonsense Mutation (SNP) | VAF 84/231 reads (36%) | catalogued as COSV63076239; called by muse, mutect2, varscan2
- DDX10 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59439116; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 66/176 reads (38%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND11 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768326324, COSV72097797; called by muse, mutect2, varscan2
- DHRS7C | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756235330, COSV57652380; called by muse, mutect2, varscan2
- DHX30 | c.2060G>A p.R687H (on ENST00000445061 / NM_138615.3; = p.R648H on NM_014966.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as rs1039273030, COSV53141879; called by muse, mutect2, varscan2
- DHX30 | c.3192-4C>A | Splice Region (SNP) | VAF 29/89 reads (33%) | catalogued as COSV99276270; called by muse, mutect2, varscan2
- DHX34 | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs199881839; called by muse, mutect2, varscan2
- DHX38 | c.3473G>A p.R1158Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.336); catalogued as rs954216217, COSV51700516; called by muse, mutect2, varscan2
- DHX57 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1290963826, COSV54882222, COSV54891848; called by muse, mutect2, varscan2
- DIP2B | c.2498T>C p.L833S | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56590768; called by muse, mutect2, varscan2
- DIS3L | c.1420G>A p.V474I (on ENST00000319212 / NM_001143688.3; = p.V391I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as rs535971311, COSV59912249; called by muse, mutect2, varscan2
- DLEC1 | c.2709G>T p.Q903H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV57305484; called by muse, mutect2, varscan2
- DLGAP5 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as rs766933512, COSV55962098; called by muse, mutect2, varscan2
- DLST | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167662; called by muse, mutect2, varscan2
- DMAC1 | c.203T>C p.V68A | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100830330; called by muse, mutect2, varscan2
- DMAP1 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); catalogued as rs948379587, COSV60001641; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH17 | c.3290C>T p.A1097V | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1157496083, COSV67760728; called by muse, mutect2, varscan2
- DNAH2 | c.8108A>G p.Y2703C | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756506359, COSV66725495; called by muse, mutect2, varscan2
- DNAH3 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1178099723, COSV54531763; called by muse, mutect2, varscan2
- DNAH7 | c.5798T>C p.L1933S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56781724; called by muse, mutect2, varscan2
- DND1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56909025; called by muse, mutect2, varscan2
- DNMT3A | c.75C>T p.D25= | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as rs538820253, COSV53063047, COSV53083210; called by muse, mutect2, varscan2
- DNMT3B | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs778795266, COSV52422312; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK5 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV52409617; called by muse, mutect2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | catalogued as rs748134881; called by mutect2, varscan2
- DOCK9 | c.67del p.L23Cfs*25 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs751315109; called by mutect2, pindel, varscan2
- DOK7 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV60773585; called by muse, varscan2
- DOP1A | c.4043A>G p.D1348G | Missense Mutation (SNP) | VAF 98/271 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV52716687; called by muse, mutect2, varscan2
- DOT1L | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67111421; called by muse, mutect2, varscan2
- DPH2 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52545139; called by muse, mutect2, varscan2
- DPP10 | c.1099T>C p.W367R | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59717978; called by muse, mutect2, varscan2
- DPY19L1 | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV60583921; called by muse, mutect2, varscan2
- DPY19L4 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV68963671; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 133/416 reads (32%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DQX1 | c.1710G>A p.M570I | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as rs759725464, COSV52047044; called by muse, mutect2, varscan2
- DRD5 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.084); catalogued as COSV58580053; called by muse, mutect2, varscan2
- DROSHA | c.2782G>A p.G928R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100757849, COSV60781673; called by muse, mutect2, varscan2
- DSCAML1 | c.5140C>T p.R1714W (on ENST00000321322; = p.R1654W on NM_020693.4) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746721038, COSV58401053; called by muse, mutect2, varscan2
- DST | c.19327C>T p.Q6443* (on ENST00000361203 / NM_001374722.1; = p.Q4140* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 65/183 reads (36%) | catalogued as COSV55035853; called by muse, mutect2, varscan2
- DST | c.18967T>A p.S6323T (on ENST00000361203 / NM_001374722.1; = p.S4020T on NM_015548.5) | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); catalogued as COSV55035864; called by muse, mutect2, varscan2
- DST | c.17223del p.K5741Nfs*2 (on ENST00000361203 / NM_001374722.1; = p.K3438Nfs*2 on NM_015548.5) | Frame Shift Del (DEL) | VAF 26/50 reads (52%) | catalogued as rs756726565; called by mutect2, varscan2
- DST | c.4496del p.L1499Wfs*8 (on ENST00000361203 / NM_001374722.1; = p.L1173Wfs*8 on NM_015548.5) | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | catalogued as rs35805169; called by mutect2, pindel, varscan2
- DUSP18 | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.425); catalogued as COSV58181443; called by muse, mutect2
- E2F2 | c.808A>G p.K270E | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1037029186, COSV62276753; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 69/102 reads (68%) | catalogued as rs369293935; called by mutect2, varscan2
- EEF1AKNMT | c.778C>T p.R260C (on ENST00000361735 / NM_015935.5; = p.R174C on NM_014955.3) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as rs777226189, COSV62283321; called by muse, mutect2, varscan2
- EEF2 | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1313275839, COSV58580754; called by muse, mutect2, varscan2
- EGR2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV54348658, COSV99654280; called by muse, mutect2, varscan2
- EIF2B4 | c.409A>C p.T137P (on ENST00000347454 / NM_001034116.2; = p.T136P on NM_015636.3) | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV52009994; called by muse, varscan2
- EIF4G1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1301375216, COSV59993458; called by muse, mutect2
- ELAVL4 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV63918772; called by muse, varscan2
- ELOVL1 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.531); catalogued as COSV60522878; called by muse, mutect2, varscan2
- EMILIN1 | c.2164A>C p.S722R | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.522); catalogued as COSV53156908; called by muse, mutect2, varscan2
- ENOX1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54915107; called by muse, mutect2, varscan2
- ENTPD8 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs779751159, COSV58163478; called by muse, mutect2, varscan2
- ENTPD8 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58163485; called by muse, mutect2, varscan2
- EP300 | c.7102G>A p.D2368N | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV54343198; called by muse, mutect2, varscan2
- EPB41L4B | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV63124365; called by muse, mutect2, varscan2
- EPG5 | c.320del p.G107Efs*26 | Frame Shift Del (DEL) | VAF 55/196 reads (28%) | catalogued as COSV99957697; called by mutect2, pindel, varscan2
- ERAP2 | c.2791T>C p.F931L | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV65941157; called by muse, mutect2, varscan2
- ERBB3 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57252242; called by muse, mutect2, varscan2
- ERN2 | c.2380G>A p.V794I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs144279415; called by muse, varscan2
- ERN2 | c.466del p.R156Afs*43 | Frame Shift Del (DEL) | VAF 25/134 reads (19%) | catalogued as rs760310462, COSV56838101; called by mutect2, pindel, varscan2
- ESRP1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344070630, COSV64412266; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 86/152 reads (57%) | catalogued as rs775950025; called by mutect2, varscan2
- F8 | c.6465del p.K2155Nfs*31 | Frame Shift Del (DEL) | VAF 70/120 reads (58%) | catalogued as CD910500; called by mutect2, pindel, varscan2
- FAF2 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs764514819, COSV56132833; called by muse, mutect2, varscan2
- FAM110B | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64067613; called by muse, mutect2, varscan2
- FAM124A | c.934A>G p.S312G (on ENST00000322475 / NM_001242312.2; = p.S348G on NM_145019.4) | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV54479600; called by muse, mutect2
- FAM135A | c.1169C>A p.P390H (on ENST00000370479 / NM_001351599.1; = p.P373H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52057877; called by muse, mutect2, varscan2
- FAM47A | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV60494861; called by muse, mutect2, varscan2
- FAM83A | c.481-2A>G p.X161_splice | Splice Site (SNP) | VAF 87/436 reads (20%) | catalogued as COSV52687656; called by muse, mutect2, varscan2
- FAM83E | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs773075907, COSV52378380; called by muse, mutect2, varscan2
- FAM83E | c.119G>A p.S40N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV50032278; called by muse, mutect2, varscan2
- FAM83H | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs892754238, COSV66354549; called by muse, mutect2, varscan2
- FANCA | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV66883382; called by muse, mutect2, varscan2
- FAT2 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55827930; called by muse, varscan2
- FAT3 | c.8678T>C p.V2893A | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs548024174, COSV53163627; called by muse, mutect2, varscan2
- FAT4 | c.1711A>C p.T571P | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.429); catalogued as COSV67883254; called by muse, mutect2, varscan2
- FAT4 | c.10930G>A p.D3644N | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58704519; called by muse, mutect2, varscan2
- FBLL1 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776764036, COSV57924845; called by muse, varscan2
- FBN3 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs139750989; called by muse, mutect2, varscan2
- FBXO48 | c.83del p.N28Mfs*33 | Frame Shift Del (DEL) | VAF 37/142 reads (26%) | catalogued as rs1558521143; called by mutect2, pindel, varscan2
- FDPS | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs373639609, COSV100756263; called by muse, mutect2, varscan2
- FER | c.1553G>A p.G518D | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55302971; called by muse, mutect2, varscan2
- FER1L6 | c.3708dup p.G1237Rfs*9 | Frame Shift Ins (INS) | VAF 28/124 reads (23%) | catalogued as rs747094222; called by mutect2, varscan2
- FER1L6 | c.5359C>T p.R1787* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as rs747557262, COSV67551442; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 72/239 reads (30%) | catalogued as rs748969702; called by mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 103/313 reads (33%) | catalogued as COSV58769165; called by mutect2, varscan2
- FKBP4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs1062478; called by muse, mutect2, varscan2
- FLG2 | c.3748A>G p.S1250G | Missense Mutation (SNP) | VAF 137/362 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66172282; called by muse, mutect2, varscan2
- FLNA | c.5097C>A p.D1699E (on ENST00000369850 / NM_001110556.2; = p.D1691E on NM_001456.3) | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as COSV61050005, COSV61052539; called by muse, mutect2, varscan2
- FLNC | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as COSV57963208; called by muse, mutect2, varscan2
- FLT3 | c.2073del p.F691Lfs*13 | Frame Shift Del (DEL) | VAF 40/141 reads (28%) | catalogued as COSV54050694; called by mutect2, pindel, varscan2
- FLT4 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs148392893, COSV56112199, COSV56119760; called by muse, mutect2, varscan2
- FLYWCH1 | c.1652G>T p.R551L (on ENST00000253928 / NM_001308068.2; = p.R550L on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99559248; called by muse, varscan2
- FOLR2 | c.523T>G p.Y175D | Missense Mutation (SNP) | VAF 119/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53351925, COSV53352331; called by muse, mutect2, varscan2
- FOXD4L1 | c.1051T>C p.Y351H | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99380825; called by muse, mutect2, varscan2
- FOXO3 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1349431368, COSV100670203; called by muse, mutect2, varscan2
- FOXP2 | c.261G>A p.V87= | Splice Region (SNP) | VAF 14/302 reads (5%) | catalogued as COSV63492810; called by muse, mutect2
- FRMD8 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV58213934; called by muse, mutect2, varscan2
- FRYL | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs764934339, COSV51941758; called by muse, mutect2, varscan2
- FURIN | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99184794; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GALR2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs142971884; called by muse, mutect2, varscan2
- GAPDHS | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs202022657, COSV55880431; called by muse, mutect2, varscan2
- GATC | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs896029723, COSV57571061; called by muse, mutect2, varscan2
- GCLM | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV64687492; called by muse, mutect2, varscan2
- GCN1 | c.7867C>T p.R2623W | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56113761; called by muse, mutect2, varscan2
- GFOD1 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV64955290; called by muse, mutect2, varscan2
- GGT7 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs1568941335, COSV60542474; called by muse, mutect2
- GIN1 | c.1321G>C p.V441L | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV67537648; called by muse, mutect2, varscan2
- GIPC1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.885); catalogued as rs1404951331, COSV61775036; called by muse, mutect2, varscan2
- GJD4 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58703287; called by muse, mutect2
- GK2 | c.1605dup p.I536Yfs*4 | Frame Shift Ins (INS) | VAF 43/171 reads (25%) | catalogued as rs752070089; called by mutect2, pindel, varscan2
- GLDC | c.255G>A p.A85= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as COSV58684137; called by muse, mutect2, varscan2
- GLDN | c.1100A>G p.Y367C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV59092042; called by muse, mutect2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 239/427 reads (56%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLUD1 | c.931A>G p.N311D | Missense Mutation (SNP) | VAF 116/453 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV53280864; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAI2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs782599019, COSV56493897; called by muse, mutect2, varscan2
- GNB4 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.44); PolyPhen probably damaging (1); catalogued as rs1404957064, COSV51710078, COSV99224669; called by muse, mutect2, varscan2
- GNE | c.116G>A p.R39Q (on ENST00000396594 / NM_001128227.3; = p.R8Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/229 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs763057654, COSV64951324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA2 | c.2494+2T>C p.X832_splice | Splice Site (SNP) | VAF 230/721 reads (32%) | catalogued as COSV57855529; called by muse, mutect2, varscan2
- GPATCH2 | c.634del p.R212Efs*3 | Frame Shift Del (DEL) | VAF 73/213 reads (34%) | catalogued as rs945102298; called by mutect2, pindel, varscan2
- GPBP1L1 | c.1307T>C p.L436S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV51972568; called by mutect2, varscan2
- GPC6 | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV65533536; called by muse, mutect2, varscan2
- GPD2 | c.1302T>C p.G434= | Splice Region (SNP) | VAF 46/133 reads (35%) | catalogued as COSV60096240; called by muse, mutect2, varscan2
- GPHN | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as COSV59491127; called by muse, mutect2
- GPR137 | c.436del p.A146Pfs*8 | Frame Shift Del (DEL) | VAF 36/112 reads (32%) | catalogued as COSV57402179; called by mutect2, pindel, varscan2
- GPR158 | c.2851A>G p.T951A | Missense Mutation (SNP) | VAF 98/288 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV66280489; called by muse, mutect2, varscan2
- GPR52 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs756264752, COSV52321051; called by muse, mutect2
- GPR6 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51573297; called by muse, mutect2, varscan2
- GPR62 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59055832; called by muse, mutect2
- GRID1 | c.1758A>G p.I586M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV60049115; called by muse, mutect2, varscan2
- GRID2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200889267, COSV56185846, COSV56207492; called by muse, mutect2, varscan2
- GRINA | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); catalogued as rs369678810; called by muse, mutect2, varscan2
- GRK2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV57953735; called by muse, mutect2, varscan2
- GRM2 | c.2410G>A p.V804M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323492175, COSV56587107; called by muse, mutect2, varscan2
- GRM5 | c.2321T>A p.I774N | Missense Mutation (SNP) | VAF 146/356 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59625119; called by muse, mutect2, varscan2
- GSC | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs774777528, COSV53077717; called by muse, mutect2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 120/167 reads (72%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2A1 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV53338323; called by muse, mutect2, varscan2
- GTF2H2C | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.683); catalogued as rs1213590375; called by mutect2, varscan2
- H2BC12 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as rs759189956, COSV63616656; called by muse, mutect2, varscan2
- H4C1 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55119264; called by muse, mutect2, varscan2
- H4C7 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs967059166, COSV55100414, COSV55100792; called by muse, mutect2, varscan2
- HAS3 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as rs372849295; called by muse, mutect2, varscan2
- HCN3 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs373947209; called by muse, mutect2, varscan2
- HDAC4 | c.1987C>G p.L663V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV61874531; called by muse, mutect2, varscan2
- HDAC4 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770769407, COSV61867098; called by muse, mutect2, varscan2
- HDAC9 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs749459197, COSV67783543; called by muse, mutect2, varscan2
- HDLBP | c.2827G>A p.G943S | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs561809495, COSV60500208; called by muse, mutect2, varscan2
- HELZ | c.5072A>G p.N1691S | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV62380540; called by muse, mutect2, varscan2
- HERC2 | c.5825C>T p.S1942L | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as rs1029004398, COSV55345908; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 52/172 reads (30%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HKDC1 | c.2729T>C p.L910S | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV100664582, COSV63578980; called by muse, mutect2, varscan2
- HLA-E | c.805G>T p.V269L | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.815); catalogued as rs1338142002, COSV64927883; called by muse, mutect2, varscan2
- HLF | c.297del p.S100Afs*106 | Frame Shift Del (DEL) | VAF 106/336 reads (32%) | catalogued as COSV56830780; called by mutect2, pindel, varscan2
- HMCN1 | c.13849T>A p.S4617T | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV54934400; called by muse, mutect2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 44/106 reads (42%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPDL | c.953A>C p.Q318P | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55023415; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2207C>A p.P736H | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.438); catalogued as COSV54566385; called by muse, mutect2, varscan2
- HOXD10 | c.133A>G p.T45A | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV50902451, COSV50907621; called by muse, mutect2, varscan2
- HPCAL4 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs375461274; called by muse, mutect2, varscan2
- HRNR | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV64262090; called by muse, mutect2, varscan2
- HSD11B2 | c.708A>C p.K236N | Missense Mutation (SNP) | VAF 113/324 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52099614; called by muse, mutect2, varscan2
- HSPG2 | c.6526C>T p.P2176S | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.17); catalogued as COSV65976364; called by muse, mutect2, varscan2
- HTR2C | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 304/425 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.369); catalogued as rs1556486892, COSV52219021; called by muse, mutect2, varscan2
- HTR5A | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV55286807; called by muse, mutect2, varscan2
- IBTK | c.3761A>G p.N1254S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60395557; called by muse, mutect2, varscan2
- IBTK | c.3638del p.K1213Sfs*50 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | catalogued as rs757667533; called by mutect2, pindel, varscan2
- IFT52 | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 128/411 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV65975952; called by muse, mutect2, varscan2
- IGF2R | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750670588, COSV63631581, COSV63632187; called by muse, mutect2, varscan2
- IGLV10-54 | c.179A>C p.Q60P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101135444; called by muse, mutect2, varscan2
- IGLV3-16 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs7285911; called by muse, varscan2
- IGSF9 | c.1624T>C p.W542R (on ENST00000368094 / NM_001135050.2; = p.W526R on NM_020789.4) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63641999; called by muse, mutect2, varscan2
- IKZF2 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs146574423; called by muse, varscan2
- IL11RA | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs745960183, COSV52405391; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61156383, COSV61177867; called by muse, mutect2, varscan2
- IL36G | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs780697688, COSV52077685; called by muse, mutect2, varscan2
- INKA1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889709783, COSV58525951; called by muse, mutect2, varscan2
- INSRR | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as rs772428423, COSV63876754; called by muse, mutect2, varscan2
- INTS4 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs765120138, COSV101417186, COSV71087626; called by muse, mutect2, varscan2
- IPO13 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs888903190, COSV64894968; called by muse, mutect2, varscan2
- IRF2BP1 | c.367del p.L123Cfs*39 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV56195278; called by mutect2, varscan2
- IRF2BPL | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs1298325850, COSV53148696; called by muse, mutect2, varscan2
- IRX6 | c.1279T>C p.C427R | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1225830015, COSV51861944; called by muse, mutect2, varscan2
- ITGA3 | c.858G>T p.Q286H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV50335233; called by muse, mutect2, varscan2
- ITGA5 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.714); catalogued as COSV53220256; called by muse, mutect2, varscan2
- ITGA6 | c.1022_1024del p.L341del (on ENST00000442250; = p.L302del on NM_000210.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 43/121 reads (36%) | catalogued as rs1318622655; called by pindel, varscan2
- JADE2 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1402512436, COSV50928770; called by muse, mutect2, varscan2
- KANK1 | c.1106A>G p.Q369R | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV63214714; called by muse, mutect2, varscan2
- KAT8 | c.708del p.E239Rfs*50 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs773168027, COSV54895512; called by mutect2, pindel, varscan2
- KATNA1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 60/168 reads (36%) | catalogued as rs372912527; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 45/173 reads (26%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNA5 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52908176; called by muse, mutect2, varscan2
- KCNAB3 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | catalogued as rs1476437035, COSV58141910; called by muse, mutect2, varscan2
- KCNB2 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.273); catalogued as COSV73052539; called by muse, mutect2, varscan2
- KCNK18 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748343807, COSV57972943; called by muse, mutect2, varscan2
- KCNK5 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs145388113; called by muse, mutect2, varscan2
- KCNS2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54640824; called by muse, mutect2, varscan2
- KCNT1 | c.35del p.G12Afs*43 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as COSV100039855; called by mutect2, pindel, varscan2
- KCTD6 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57150506; called by muse, mutect2, varscan2
- KDM4A | c.2821C>T p.L941F | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64960504; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 94/222 reads (42%) | catalogued as rs771545848; called by mutect2, varscan2
- KDM5A | c.1615A>G p.I539V | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV66995749; called by muse, mutect2, varscan2
- KDM5C | c.2848A>G p.M950V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV64768595; called by muse, mutect2, varscan2
- KDM5C | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV64763034, COSV64770254; called by muse, mutect2, varscan2
- KHDRBS2 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55486054, COSV99832646; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 50/173 reads (29%) | catalogued as rs1339576763; called by mutect2, varscan2
- KIAA1958 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV61725878; called by muse, mutect2
- KIF13A | c.5256T>A p.D1752E | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV52463439; called by muse, mutect2
- KIF13B | c.4567del p.A1523Pfs*4 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1433031821; called by mutect2, varscan2
- KIF16B | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 139/374 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.202); catalogued as COSV61712825; called by muse, mutect2, varscan2
- KIF21B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs770974908, COSV59752730; called by muse, mutect2, varscan2
- KIF26A | c.1489T>C p.S497P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59470016; called by muse, mutect2, varscan2
- KIF2C | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV64765524; called by muse, mutect2, varscan2
- KIF5B | c.2623A>G p.K875E | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV56655791; called by muse, mutect2, varscan2
- KIFBP | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as COSV62832376; called by muse, mutect2, varscan2
- KIRREL2 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV52875041; called by muse, mutect2, varscan2
- KLC4 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs760931254, COSV52438864; called by muse, mutect2
- KLF16 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1464155965, COSV51736425; called by muse, mutect2, varscan2
- KLHDC7B | c.983G>A p.R328Q (on ENST00000395676; = p.R969Q on NM_138433.5) | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763759553, COSV67465179; called by muse, varscan2
- KLHDC7B | c.1040G>A p.C347Y (on ENST00000395676; = p.C988Y on NM_138433.5) | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67465184; called by muse, varscan2
- KLHL2 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 35/107 reads (33%) | catalogued as COSV56979220; called by muse, mutect2, varscan2
- KLHL20 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as rs749524628, COSV52943034, COSV52944636; called by muse, mutect2, varscan2
- KLHL20 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 150/398 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52944647; called by muse, varscan2
- KMT2A | c.5047C>T p.R1683C | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs377724112; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as COSV55868319; called by mutect2, varscan2
- KMT2E | c.5203T>C p.S1735P | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV57578723; called by muse, mutect2, varscan2
- KNTC1 | c.3899T>C p.F1300S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV61083493; called by mutect2, varscan2
- KREMEN1 | c.197A>G p.Y66C (on ENST00000407188; = p.Y68C on NM_032045.5) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59914502; called by muse, mutect2, varscan2
- KRT18 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV66316598; called by muse, mutect2, varscan2
- KRT33A | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs552619720, COSV50374101; called by muse, mutect2, varscan2
- KRT74 | c.1393G>T p.V465F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV59771389, COSV59773434; called by muse, mutect2
- KRT75 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.123); catalogued as rs139460759; called by muse, mutect2, varscan2
- KRTAP13-2 | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as COSV67762269; called by muse, mutect2, varscan2
- KRTAP5-2 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 59/356 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.84); catalogued as COSV69015506; called by muse, varscan2
- KRTAP5-8 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 194/595 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.272); catalogued as COSV68324899; called by muse, mutect2, varscan2
- KYAT3 | c.1302A>G p.K434= | Splice Region (SNP) | VAF 134/447 reads (30%) | catalogued as rs775867816, COSV53105037; called by muse, mutect2, varscan2
- KYNU | c.1200del p.C401Afs*3 | Frame Shift Del (DEL) | VAF 39/135 reads (29%) | catalogued as COSV51587622; called by mutect2, pindel, varscan2
- LAMA2 | c.3656C>T p.A1219V | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as COSV70353644; called by muse, mutect2, varscan2
- LAMA5 | c.9128T>C p.V3043A | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); catalogued as COSV53370602; called by muse, varscan2
- LAMB3 | c.1012del p.A338Hfs*58 | Frame Shift Del (DEL) | VAF 73/218 reads (33%) | catalogued as rs1211747169; called by mutect2, pindel, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 128/426 reads (30%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LCE5A | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV57501425; called by muse, mutect2, varscan2
- LENG9 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV56619708; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LHX2 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449784215, COSV65319011; called by muse, mutect2, varscan2
- LHX6 | c.594C>T p.N198= (on ENST00000373755 / NM_001242334.2; = p.N227= on NM_014368.5) | Splice Region (SNP) | VAF 29/106 reads (27%) | catalogued as COSV61346043; called by muse, mutect2, varscan2
- LIG3 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs1306395065, COSV52010494; called by muse, mutect2, varscan2
- LIMS2 | c.404T>C p.L135P (on ENST00000355119 / NM_001161403.3; = p.L159P on NM_017980.4) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as rs1183186741, COSV55756840; called by muse, mutect2, varscan2
- LMAN1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 70/228 reads (31%) | catalogued as rs951475866, CM990809, COSV51826707; called by muse, mutect2, varscan2
- LNPEP | c.2858T>C p.V953A | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs1208662941, COSV51480752; called by muse, mutect2, varscan2
- LOXL1 | c.1195_1197del p.E399del | In Frame Del (DEL) | VAF 70/214 reads (33%) | catalogued as rs775555226; called by pindel, varscan2
- LRIG1 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs905039845, COSV56247078; called by muse, mutect2, varscan2
- LRP2 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55570305; called by muse, mutect2, varscan2
- LRRC47 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1442091031, COSV65562920, COSV65563601; called by muse, varscan2
- LRRC47 | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1357490076, COSV65563605; called by muse, varscan2
- LRRC66 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV58636400; called by muse, mutect2
- LRRC75B | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV50644451; called by muse, mutect2, varscan2
- MACF1 | c.13249G>T p.G4417* (on ENST00000372915; = p.G2350* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 58/155 reads (37%) | catalogued as COSV57132497; called by muse, mutect2, varscan2
- MAD1L1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1412116610, COSV56245674; called by muse, mutect2, varscan2
- MAEL | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs750796269, COSV100901860, COSV63306129; called by muse, mutect2, varscan2
- MAGEA4 | c.742A>G p.T248A | Missense Mutation (SNP) | VAF 117/166 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV52342788; called by muse, varscan2
- MAGEL2 | c.2508G>T p.W836C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV58568814; called by muse, mutect2, varscan2
- MAML3 | c.2626A>G p.T876A | Missense Mutation (SNP) | VAF 172/725 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1345623241, COSV72210016; called by muse, mutect2, varscan2
- MAP2K7 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755099146, COSV101208977, COSV67607952, COSV67609638; called by muse, mutect2, varscan2
- MAP2K7 | c.1063T>C p.S355P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV67609643; called by muse, mutect2, varscan2
- MAP3K21 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV64042421; called by muse, mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 152/224 reads (68%) | catalogued as rs746202015; called by mutect2, varscan2
- MARK3 | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs779860437, COSV53508898; called by muse, mutect2, varscan2
- MARK4 | c.1923-2A>G p.X641_splice (on ENST00000262891 / NM_001199867.2; = p.X668_splice on NM_031417.4) | Splice Site (SNP) | VAF 273/746 reads (37%) | catalogued as COSV53468083; called by muse, mutect2, varscan2
- MAST2 | c.4081C>T p.R1361W | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1028778451, COSV63621012; called by muse, mutect2, varscan2
- MBD1 | c.475+2T>C p.X159_splice | Splice Site (SNP) | VAF 34/86 reads (40%) | catalogued as COSV54006264; called by muse, mutect2, varscan2
- MBD6 | c.2200dup p.Q734Pfs*4 | Frame Shift Ins (INS) | VAF 93/282 reads (33%) | catalogued as rs749738168; called by mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 30/114 reads (26%) | catalogued as rs746267361; called by mutect2, varscan2
- MBTPS1 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149564178, COSV58572296; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 45/122 reads (37%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM2 | c.2439C>G p.S813R | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs755267976, COSV54036901; called by muse, mutect2, varscan2
- MCM3AP | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52444743, COSV99387097; called by muse, mutect2, varscan2
- MCM4 | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757711165, COSV50631136; called by muse, mutect2, varscan2
- MCMDC2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs774182901, COSV58033832, COSV58040182; called by muse, mutect2, varscan2
- MCMDC2 | c.1144A>G p.T382A | Missense Mutation (SNP) | VAF 72/435 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as COSV58040229; called by muse, mutect2, varscan2
- MDN1 | c.13891A>G p.T4631A | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1383613677, COSV65528915; called by muse, mutect2, varscan2
- MED12L | c.5834G>A p.G1945E | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.495); catalogued as COSV56393982; called by muse, mutect2, varscan2
- MED16 | c.323G>A p.W108* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV54131157; called by muse, mutect2, varscan2
- MEFV | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs104895096, CM012154, COSV54820562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- METTL16 | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 26/401 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as COSV54012660; called by muse, mutect2
- MFHAS1 | c.1420A>G p.I474V | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52286374; called by muse, mutect2, varscan2
- MFSD6L | c.1660T>C p.S554P | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756059322, COSV61688807; called by muse, mutect2, varscan2
- MICAL3 | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV52904218; called by muse, mutect2, varscan2
- MICU2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV101212495; called by muse, mutect2, varscan2
- MIER1 | c.728C>T p.A243V (on ENST00000355356 / NM_001077701.3; = p.A260V on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV62531903; called by muse, mutect2, varscan2
- MISP | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.436); catalogued as rs761558996, COSV53120026; called by muse, mutect2, varscan2
- MLXIPL | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100515560; called by muse, mutect2, varscan2
- MME | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs369531733; called by muse, mutect2, varscan2
- MMP8 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs546201458, COSV52634119; called by muse, mutect2, varscan2
- MON2 | c.3926T>C p.V1309A | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV54813778; called by muse, mutect2, varscan2
- MORN1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147757432; called by muse, mutect2, varscan2
- MPP1 | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV65728689; called by muse, mutect2
- MRC1 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV100509704; called by muse, mutect2, varscan2
- MRGPRX3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs141255495; called by muse, mutect2, varscan2
- MRPS15 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as rs375296349; called by muse, mutect2, varscan2
- MSGN1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1033176403, COSV55263697; called by muse, mutect2, varscan2
- MSL2 | c.379_381del p.S127del | In Frame Del (DEL) | VAF 68/249 reads (27%) | catalogued as rs776108533; called by pindel, varscan2
- MTCL1 | c.4181G>A p.R1394H (on ENST00000306329 / NM_001378206.1; = p.R1075H on NM_015210.4) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs367681723; called by muse, mutect2, varscan2
- MTF2 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64772020; called by muse, mutect2, varscan2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 38/153 reads (25%) | catalogued as rs767880823; called by mutect2, varscan2
- MTNR1A | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV56157565; called by mutect2, varscan2
- MTOR | c.1151A>G p.K384R | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1553128720, COSV63877292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC17 | c.6602C>G p.S2201C | Missense Mutation (SNP) | VAF 322/820 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV60300827; called by muse, mutect2, varscan2
- MXRA5 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs368770345, COSV54247603; called by muse, mutect2, varscan2
- MXRA8 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV58511593; called by muse, mutect2, varscan2
- MYBPC3 | c.3704T>C p.V1235A | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as CM1412261, COSV57032855; called by muse, mutect2, varscan2
- MYCBP2 | c.143A>T p.N48I (on ENST00000357337; = p.N86I on NM_015057.5) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV62036090; called by muse, mutect2, varscan2
- MYH10 | c.4900G>A p.E1634K | Missense Mutation (SNP) | VAF 198/516 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs184124261, COSV52609438; called by muse, mutect2, varscan2
- MYH3 | c.5731G>A p.A1911T | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56869258; called by muse, mutect2, varscan2
- MYH3 | c.5344C>T p.R1782W | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375945785; called by muse, mutect2, varscan2
- MYH3 | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 264/791 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs141020227; called by muse, mutect2, varscan2
- MYH3 | c.2943G>T p.E981D | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV56869288; called by muse, mutect2, varscan2
- MYO15A | c.7273G>T p.G2425C | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52764233; called by muse, mutect2, varscan2
- MYO1A | c.1202A>T p.N401I | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55656977; called by muse, mutect2, varscan2
- MYO3A | c.3232del p.I1078Yfs*10 | Frame Shift Del (DEL) | VAF 48/163 reads (29%) | catalogued as rs766927540; called by mutect2, pindel, varscan2
- MYO5A | c.1262A>G p.Q421R | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62563935; called by muse, mutect2, varscan2
- MYOM2 | c.107del p.K36Sfs*13 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as rs1360158578; called by mutect2, pindel, varscan2
- MYOM2 | c.2147G>A p.G716E | Missense Mutation (SNP) | VAF 90/365 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747830355, COSV50724747; called by muse, mutect2, varscan2
- MYORG | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99898838; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 92/304 reads (30%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- MYSM1 | c.2300G>A p.R767Q | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs200918602, COSV68978188; called by muse, mutect2, varscan2
- N4BP2 | c.1415C>T p.T472I | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773568783, COSV54706053; called by muse, mutect2, varscan2
- NACC1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 130/321 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1434792116, COSV52835737; called by muse, mutect2, varscan2
- NAIF1 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 44/116 reads (38%) | catalogued as COSV66092233; called by muse, mutect2, varscan2
- NANOS2 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58025688; called by muse, mutect2, varscan2
- NAV3 | c.3580G>A p.V1194I | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs998421963, COSV57107553; called by muse, mutect2, varscan2
- NBEA | c.2414T>C p.V805A | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV59816226; called by muse, mutect2, varscan2
- NCAM2 | c.484C>A p.R162= | Splice Region (SNP) | VAF 46/132 reads (35%) | catalogued as COSV53070568, COSV53071940; called by muse, mutect2, varscan2
- NCKAP1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV62943167; called by muse, mutect2, varscan2
- NCKAP5 | c.1783A>T p.S595C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1470642700, COSV58437290, COSV58470432; called by muse, mutect2, varscan2
- NDST1 | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); catalogued as COSV55790356; called by muse, mutect2, varscan2
- NDST2 | c.572dup p.L191Ffs*35 | Frame Shift Ins (INS) | VAF 34/100 reads (34%) | catalogued as rs764143617; called by mutect2, varscan2
- NDUFA10 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV53156273; called by muse, mutect2, varscan2
- NECTIN3 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs749596338, COSV60551540; called by muse, mutect2, varscan2
- NEK4 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 124/388 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV51782881; called by muse, mutect2, varscan2
- NELFA | c.374A>C p.N125T (on ENST00000542778; = p.N114T on NM_005663.5) | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV61607914, COSV61608052; called by muse, mutect2, varscan2
- NHLRC1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1177366108, COSV61481817; called by muse, mutect2, varscan2
- NID1 | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV51627526; called by muse, mutect2, varscan2
- NLRC5 | c.2510G>T p.R837M | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52661978; called by muse, mutect2, varscan2
- NLRP1 | c.2410C>A p.L804I | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as COSV52576487; called by muse, mutect2, varscan2
- NNT | c.2497G>A p.V833I | Missense Mutation (SNP) | VAF 119/338 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as rs1165451368, COSV52928885; called by muse, mutect2, varscan2
- NOL8 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62634212, COSV62637446; called by muse, mutect2, varscan2
- NOM1 | c.1112G>T p.R371M | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51982168; called by muse, mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | catalogued as rs746543323; called by mutect2, varscan2
- NOS3 | c.1319dup p.C441Lfs*57 | Frame Shift Ins (INS) | VAF 31/119 reads (26%) | catalogued as rs749517498; called by mutect2, varscan2
- NOSIP | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV59200165; called by muse, varscan2
- NOTCH1 | c.5810G>A p.R1937H | Missense Mutation (SNP) | VAF 154/404 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53086283; called by muse, mutect2, varscan2
- NOTCH3 | c.4937T>G p.L1646R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54646959; called by muse, mutect2
- NPBWR2 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.083); catalogued as COSV63900533; called by muse, mutect2, varscan2
- NPC1L1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs752229761, COSV56929597; called by muse, varscan2
- NPR1 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV64118053; called by muse, mutect2, varscan2
- NR1I2 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV61979530; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | catalogued as rs774343392; called by mutect2, varscan2
- NRIP1 | c.2187_2188del p.K730Nfs*6 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | catalogued as rs1178348583; called by pindel, varscan2
- NRP1 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 147/446 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55175899; called by muse, mutect2, varscan2
- NRXN3 | c.1829G>A p.C610Y (on ENST00000335750 / NM_001330195.2; = p.C237Y on NM_004796.6) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59798548; called by muse, mutect2, varscan2
- NSD3 | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 90/493 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV57618600, COSV57621584; called by muse, mutect2, varscan2
- NT5C2 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58418968; called by muse, mutect2, varscan2
- NT5DC3 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67322659; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 36/92 reads (39%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP210L | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 186/543 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV55156124; called by muse, mutect2, varscan2
- NUP214 | c.681dup p.V228Sfs*9 | Frame Shift Ins (INS) | VAF 75/247 reads (30%) | catalogued as rs771913112; called by mutect2, varscan2
- NXN | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV61099800; called by muse, mutect2, varscan2
- NXPE4 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); catalogued as COSV64943608, COSV64944310; called by muse, mutect2, varscan2
- OBP2A | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs547898380, COSV59793232; called by muse, mutect2, varscan2
- OBSCN | c.7982G>A p.R2661H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs776318810, COSV52819470; called by muse, mutect2, varscan2
- OPA1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs751318725, COSV62482962; called by muse, mutect2, varscan2
- OPLAH | c.3170T>C p.V1057A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV70679119; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 77/248 reads (31%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10H4 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1333660402, COSV59062812; called by muse, mutect2, varscan2
- OR10Q1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV57471796; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 39/120 reads (33%) | catalogued as rs761899382; called by mutect2, varscan2
- OR14J1 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 136/379 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65845947; called by muse, mutect2, varscan2
- OR2A7 | c.532del p.C178Vfs*37 | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | catalogued as rs749245232; called by mutect2, pindel, varscan2
- OR2F2 | c.488C>G p.T163S | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs779736615, COSV68833231; called by muse, mutect2, varscan2
- OR2M5 | c.877C>A p.R293S | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV63546913; called by muse, mutect2, varscan2
- OR2W3 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 111/300 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV64457836; called by muse, mutect2, varscan2
- OR4S2 | c.251T>C p.L84S | Missense Mutation (SNP) | VAF 179/461 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV56748074; called by muse, mutect2, varscan2
- OR51B2 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV60917534; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51I1 | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1187630456, COSV66508997; called by muse, mutect2, varscan2
- OR5H1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV63403369; called by muse, mutect2, varscan2
- OR6C70 | c.304dup p.Y102Lfs*18 | Frame Shift Ins (INS) | VAF 38/148 reads (26%) | catalogued as rs750079585; called by mutect2, varscan2
- OR6K3 | c.703A>G p.R235G (on ENST00000368146; = p.R219G on NM_001005327.2) | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as COSV63746352; called by muse, mutect2, varscan2
- OR7G2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59688822; called by muse, mutect2
- OR7G2 | c.384dup p.A129Cfs*14 | Frame Shift Ins (INS) | VAF 50/148 reads (34%) | catalogued as rs750339447; called by mutect2, pindel, varscan2
- OR7G2 | c.245T>C p.F82S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV59688831; called by muse, mutect2, varscan2
- OSBPL1A | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60203062; called by muse, mutect2, varscan2
- OSBPL5 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372071423; called by muse, mutect2, varscan2
- OSBPL9 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs764308850, COSV61874163; called by muse, mutect2, varscan2
- OTOF | c.5440A>G p.M1814V (on ENST00000272371 / NM_194248.3; = p.M1047V on NM_004802.4) | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs886055874, COSV55516656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTUD4 | c.981G>T p.K327N (on ENST00000447906 / NM_001366057.1; = p.K262N on NM_001102653.1) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV71381822; called by muse, mutect2, varscan2
- OXSR1 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 64/211 reads (30%) | catalogued as COSV61260306; called by muse, mutect2, varscan2
- PADI3 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64935270; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.649C>T p.H217Y (on ENST00000374531 / NM_001037293.2; = p.H249Y on NM_053016.6) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57130625; called by muse, mutect2, varscan2
- PARD3B | c.2023A>G p.S675G | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV62504977, COSV62534042; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PARP1 | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV64691908; called by muse, mutect2, varscan2
- PARP8 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs755306291, COSV55865701; called by muse, mutect2, varscan2
- PAX1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs767391855, COSV68272006, COSV68272053; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 39/134 reads (29%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PAX9 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100825896; called by muse, mutect2, varscan2
- PCDH12 | c.2965C>A p.P989T | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as rs1200529574, COSV51524041; called by muse, mutect2, varscan2
- PCDH8 | c.3011A>G p.Y1004C | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1163803685, COSV58812453; called by muse, mutect2
- PCDHA1 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV65375149; called by muse, mutect2, varscan2
- PCDHA11 | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 134/341 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV56539326; called by muse, mutect2, varscan2
- PCDHA12 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs566250084, COSV56539344; called by muse, varscan2
- PCDHA8 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 67/84 reads (80%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as rs1554139718, COSV65331850; called by muse, mutect2, varscan2
- PCDHA8 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.085); catalogued as COSV65325508, COSV65331589; called by muse, mutect2, varscan2
- PCDHB14 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 158/438 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.677); catalogued as rs142658705; called by muse, varscan2
- PCDHB2 | c.223del p.M75Cfs*14 | Frame Shift Del (DEL) | VAF 42/139 reads (30%) | catalogued as rs782086614; called by mutect2, varscan2
- PCDHB8 | c.1904A>G p.D635G | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV50786042; called by muse, mutect2, varscan2
- PCDHGA6 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.125); catalogued as rs181747779, COSV53986672; called by muse, mutect2, varscan2
- PCDHGB1 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.614); catalogued as COSV54056920; called by muse, mutect2, varscan2
- PCID2 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV55814929; called by muse, mutect2, varscan2
- PCLO | c.7575del p.K2525Nfs*14 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | catalogued as COSV61632931, COSV61638903; called by mutect2, pindel, varscan2
- PDE4A | c.938C>T p.A313V (on ENST00000380702 / NM_001111307.2; = p.A74V on NM_006202.3) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs201202869, COSV53361324; called by muse, mutect2, varscan2
- PDE5A | c.2204T>C p.F735S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53352111; called by muse, varscan2
- PDLIM7 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as rs753547502, COSV62883753; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 33/42 reads (79%) | catalogued as rs759495724; called by mutect2, varscan2
- PDZD2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 127/302 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs368272828; called by muse, mutect2, varscan2
- PER1 | c.1396del p.L466* | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs773913770; called by pindel, varscan2
- PER1 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1005080461, COSV57917506; called by muse, varscan2
- PEX2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV63814161; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF7 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.947); catalogued as COSV59979827; called by muse, mutect2, varscan2
- PHIP | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 129/354 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.122); catalogued as COSV51509422; called by muse, mutect2, varscan2
- PI4K2B | c.1163A>G p.D388G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1469703471, COSV53512824; called by muse, mutect2, varscan2
- PI4KA | c.6149G>A p.R2050H | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs554944815, COSV55421203; called by muse, mutect2, varscan2
- PIGC | c.247del p.H83Ifs*4 | Frame Shift Del (DEL) | VAF 56/154 reads (36%) | catalogued as rs1176830810; called by mutect2, pindel, varscan2
- PIP5K1C | c.1945T>C p.Y649H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58955394; called by muse, varscan2
- PIWIL1 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs753282833, COSV55344954; called by muse, mutect2, varscan2
- PKD1L1 | c.7493C>T p.T2498M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as rs367611487; called by muse, mutect2, varscan2
- PKD1L1 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV56975849; called by muse, mutect2, varscan2
- PKN1 | c.2792C>T p.A931V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs749748800, COSV52876276; called by muse, mutect2, varscan2
- PLAAT4 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs368947257; called by muse, mutect2, varscan2
- PLAC8 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV61048160; called by muse, mutect2, varscan2
- PLCXD3 | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 122/272 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as COSV60616445; called by muse, mutect2, varscan2
- PLEC | c.11347C>T p.R3783C (on ENST00000322810 / NM_201380.4; = p.R3673C on NM_000445.5) | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs202175941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG1 | c.3088G>A p.A1030T | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745737557, COSV62046507; called by muse, mutect2, varscan2
- PLEKHG4 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763106385, COSV64613937; called by muse, mutect2, varscan2
- PLEKHG5 | c.484T>A p.S162T (on ENST00000400915 / NM_001042663.3; = p.S125T on NM_020631.6) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61705475; called by muse, mutect2, varscan2
- PLEKHM1 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV69599376; called by muse, mutect2, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 40/124 reads (32%) | catalogued as rs765091847; called by mutect2, varscan2
- PLK1 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55624054; called by muse, mutect2, varscan2
- PLPP7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs373987134; called by muse, mutect2, varscan2
- PLXNA4 | c.4985A>G p.D1662G | Missense Mutation (SNP) | VAF 144/493 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58155465; called by muse, mutect2, varscan2
- PNISR | c.1788A>T p.R596S | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV65080569; called by muse, mutect2, varscan2
- PNMA1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV54098116; called by muse, mutect2, varscan2
- PNMA3 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1366003298, COSV64722872; called by muse, mutect2, varscan2
- PNPLA8 | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV57554413; called by muse, mutect2
- POLE | c.6748-2A>C p.X2250_splice | Splice Site (SNP) | VAF 30/81 reads (37%) | catalogued as COSV100268283; called by muse, varscan2
- POLM | c.290dup p.A98Sfs*73 | Frame Shift Ins (INS) | VAF 49/148 reads (33%) | catalogued as rs745933237; called by mutect2, varscan2
- POLQ | c.5393C>A p.P1798H | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV51759846; called by muse, mutect2, varscan2
- POLR3C | c.590-2A>G p.X197_splice | Splice Site (SNP) | VAF 76/202 reads (38%) | catalogued as COSV61937371; called by muse, mutect2, varscan2
- POLR3G | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV67626215; called by muse, mutect2, varscan2
- POMC | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53035573; called by muse, mutect2
- POP1 | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV62894006; called by muse, mutect2, varscan2
- POU4F3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57944740; called by muse, mutect2, varscan2
- PPARA | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53081023; called by muse, mutect2, varscan2
- PPFIA2 | c.2821A>G p.R941G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61050535; called by muse, mutect2, varscan2
- PPIG | c.830T>A p.I277N | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53645577; called by muse, mutect2
- PPIL2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 148/447 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs774909103, COSV58607796; called by muse, mutect2, varscan2
- PPIP5K2 | c.2995A>G p.T999A | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.05); catalogued as COSV58605510; called by muse, varscan2
- PPP1R13L | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs768668757, COSV62909537; called by muse, mutect2, varscan2
- PPP1R26 | c.2609del p.G870Afs*84 | Frame Shift Del (DEL) | VAF 68/191 reads (36%) | catalogued as COSV63354801; called by mutect2, pindel, varscan2
- PPP1R3D | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV62565009; called by muse, mutect2, varscan2
- PPP1R7 | c.166del p.E56Rfs*28 | Frame Shift Del (DEL) | VAF 63/179 reads (35%) | catalogued as COSV52145980, COSV99297668; called by mutect2, pindel, varscan2
- PPP1R9A | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 131/352 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56908022; called by muse, mutect2, varscan2
- PPP2R5A | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 40/160 reads (25%) | catalogued as COSV54818952; called by muse, mutect2, varscan2
- PPP6R2 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs770334648, COSV53291047; called by muse, mutect2, varscan2
- PRDM10 | c.3223A>G p.T1075A | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); catalogued as COSV58804506; called by muse, mutect2, varscan2
- PRDM8 | c.1874A>G p.N625S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60204816; called by muse, mutect2, varscan2
- PRDM9 | c.2378G>A p.S793N | Missense Mutation (SNP) | VAF 96/338 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV57012029; called by muse, varscan2
- PREX2 | c.1693dup p.S565Ffs*3 | Frame Shift Ins (INS) | VAF 42/161 reads (26%) | catalogued as rs764112302; called by mutect2, varscan2
- PRICKLE1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762434475, COSV61543440; called by muse, mutect2, varscan2
965 further variants in this file (565 protein-altering or splice-affecting, 358 silent, 42 other) are not listed here.
